Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACIV, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACIV-TTP1-A (Primary Tumor).

SPECIMEN(S) RECEIVED:

- A) Right lung, middle lobe
- B) Hilar lymph node from middle lobe
- C) Hilar lymph node from lower lobe

CDDP-YP-ACIV-01-PR

GROSS EXAMINATION:

A) Lung resection measuring 11x6.5x3 cm, with retraction of visceral pleura in area of neoplasm, measuring 3.5 cm in greatest diameter, with scalloped margins, grayish-white, located 3.5 cm from the margins of bronchial resection. Remainder of parenchyma appears congested. Four peribronchial lymph nodes were isolated.

A1-A3 neoplasm

A4 margin of resection

A5 peribronchial lymph nodes

A6 distant parenchyma

B) One lymph node measuring 1.2 cm in greatest diameter.

C) One lymph node measuring 1 cm in greatest diameter.

DIAGNOSIS:

No unknown, per TSS. lu

A) Poorly differentiated (G3) adenocarcinoma of the lung, with focal papillary features and focally necrotic. No evidence of peritumoral neoplastic vascular invasion.

Bronchial and vascular margins of surgical resection and visceral pleura free of neoplasia. Focal partial atelectasis in remainder of lung parenchyma, presence of arteriovenous shunt, features of diffuse interstitial thickening with focal alveolar bronchiolization.

Nonspecific reactive lymph node inflammation with sinus histiocytosis and anthracosis in 4 lymph nodes.

B, C) Nonspecific reactive lymph node inflammation with sinus histiocytosis in 2 lymph nodes.

Histopathologic staging:

pT2N0

ICD-0-3

Intraoperative examination:

B) No evidence of neoplasia

Adenocarcinoma, NOS 8140/3

Site: (R) lung, middle lobe C34.2

ICD-10
C 34.2

lu
12/10/10

Source: NCI Genomic Data Commons file 038d0366-d815-4867-b088-f5ebb0c1d7b4 (CDDP-ACIV-TTP1.8E8C1922-CA60-4EE3-8490-6F7B97BA8023.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).